FM case AD4269 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/19e44f35-9a29-409c-99b0-d2b1bf25aa43

Female, 87.2 years: Melanoma, NOS (ICD-O-3 8720/3) of the skin; metastasis biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
